Somatic mutation profile of tumor specimen TCGA-FP-8099-01A (aliquot TCGA-FP-8099-01A-11D-2340-08) from TCGA case TCGA-FP-8099, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 79.8 years (29,129 days).
Specimen TCGA-FP-8099-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b993ffd6-04f9-4fab-927e-6ee36638a034.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-8099-10A (Blood Derived Normal), aliquot TCGA-FP-8099-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b39eb5cc-3ef1-49e4-bb7e-2bed9fb99f39

The open-access MAF lists 152 somatic variants for this specimen: 104 protein-altering or splice-affecting, 43 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 43, Nonsense Mutation 6, Frame Shift Ins 3, Splice Site 1, 5'UTR 1, 3'Flank 1, Frame Shift Del 1, Intron 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 25/29 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60786475, COSV60810612; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 34/64 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2M | c.1336C>A p.H446N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV59389380, COSV59389750; called by muse, mutect2, varscan2
- ACOX3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs142830697; called by muse, mutect2, varscan2
- ADGRE2 | c.1907A>G p.Y636C | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59695032; called by muse, mutect2, varscan2
- ANK2 | c.3254C>T p.A1085V | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759670378, COSV52175293; called by muse, mutect2, varscan2
- ARID1A | c.3539+1G>A p.X1180_splice | Splice Site (SNP) | VAF 46/73 reads (63%) | catalogued as COSV61383415, COSV61385140; called by muse, mutect2, varscan2
- BCL9 | c.3271C>G p.Q1091E | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV52347620; called by muse, mutect2
- BMS1 | c.722T>G p.V241G | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65734730; called by muse, mutect2, varscan2
- C1QTNF2 | c.537G>T p.E179D (on ENST00000393975; = p.E134D on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV67433049; called by muse, mutect2, varscan2
- CACNA1E | c.3512C>T p.A1171V | Missense Mutation (SNP) | VAF 93/176 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs968528269, COSV62382237; called by muse, mutect2, varscan2
- CHEK1 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV54024726; called by muse, mutect2
- CLSTN2 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71723143; called by muse, mutect2, varscan2
- CNMD | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1201015797, COSV65033616; called by muse, mutect2, varscan2
- COL27A1 | c.4063G>A p.G1355R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301556551, COSV61928783; called by muse, mutect2, varscan2
- CSTF1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53859511; called by muse, mutect2
- CT55 | c.335G>T p.R112I | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52278386; called by muse, mutect2, varscan2
- CTSZ | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as rs751039397, COSV53884170; called by muse, mutect2, varscan2
- CUL9 | c.6634G>A p.D2212N | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1370142548, COSV99335344; called by muse, mutect2
- DCLRE1A | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV63749210; called by muse, mutect2
- DISP2 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV51130324; called by muse, mutect2
- DISP2 | c.3082C>A p.L1028I | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51130408; called by muse, mutect2, varscan2
- DNAAF1 | c.1208C>A p.A403D | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as COSV100533805, COSV57578040; called by muse, mutect2, varscan2
- ECI1 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs939735983, COSV57040174; called by muse, mutect2, varscan2
- FAM209B | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs759472197, COSV64915870; called by muse, mutect2, varscan2
- FCN1 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as rs572824923, COSV65662677; called by muse, mutect2, varscan2
- FLNC | c.6817G>A p.A2273T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs372251350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC1 | c.5073G>T p.L1691F | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51943351; called by muse, mutect2, varscan2
- GREB1 | c.2740G>A p.V914I | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as rs139446036, COSV52188405; called by muse, mutect2, varscan2
- GRID2 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV56234120; called by muse, mutect2, varscan2
- IL6ST | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV61142172; called by muse, mutect2
- IRX1 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57359216; called by muse, mutect2, varscan2
- IVNS1ABP | c.1043A>G p.E348G | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.214); catalogued as COSV62251599; called by muse, mutect2, varscan2
- KCNA4 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV60252475; called by muse, mutect2, varscan2
- MAGEB18 | c.921G>C p.L307F | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57464612; called by muse, mutect2, varscan2
- MAK16 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs150362163; called by muse, mutect2, varscan2
- MGMT | c.101A>G p.K34R (on ENST00000306010; = p.K3R on NM_002412.5) | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.297); catalogued as COSV60031309; called by muse, mutect2
- MICAL2 | c.529A>T p.I177F | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV56323097; called by muse, mutect2, varscan2
- MIPEP | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs958203066, COSV66301390; called by muse, mutect2, varscan2
- MMP17 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs754540566, COSV62180424; called by muse, mutect2, varscan2
- MMP19 | c.224C>G p.A75G | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV59452258; called by muse, mutect2, varscan2
- MSH2 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138857091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUSK | c.2074C>G p.P692A | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.676); catalogued as COSV51891064, COSV99503835; called by muse, mutect2, varscan2
- MYCBP2 | c.4999G>A p.A1667T (on ENST00000357337; = p.A1705T on NM_015057.5) | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV62029750; called by muse, mutect2
- MYCT1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs375330501; called by muse, mutect2, varscan2
- MYOM1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs762212739, COSV55296509; called by muse, mutect2, varscan2
- NAP1L2 | c.1286A>G p.Y429C | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65172794; called by muse, mutect2, varscan2
- NEUROD4 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1010516889, COSV54472749; called by muse, mutect2, varscan2
- NEUROG1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100130717, COSV59082804; called by muse, mutect2
- NTNG1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV53979902; called by muse, mutect2, varscan2
- NTRK3 | c.2360G>A p.R787H (on ENST00000360948 / NM_001012338.2; = p.R773H on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs370533197; called by muse, mutect2, varscan2
- OGA | c.2269G>A p.G757R | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63382477; called by muse, mutect2
- OR1F1 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV58961822; called by muse, mutect2, varscan2
- OR2G6 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs545112320, COSV58573587; called by muse, mutect2, varscan2
- OR4C11 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs779245141, COSV56354308; called by muse, mutect2, varscan2
- OR4C46 | c.89T>G p.F30C | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as COSV60220479; called by muse, mutect2, varscan2
- OR6Y1 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs369288089; called by muse, mutect2, varscan2
- OTOF | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs776154354, COSV55510594; called by muse, mutect2, varscan2
- OTOF | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); catalogued as rs764248648, COSV55510605; called by muse, mutect2, varscan2
- PACS2 | c.748A>T p.N250Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV100330746; called by muse, mutect2, varscan2
- PDZD4 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs368296370, COSV51248679; called by muse, mutect2
- PLA2G4F | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767391879, COSV51828321; called by muse, mutect2, varscan2
- PLIN4 | c.2996A>C p.Q999P (on ENST00000301286; = p.Q1014P on NM_001367868.2) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs776343289, COSV56694708; called by muse, mutect2, varscan2
- PTGS1 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1423400795, COSV56293325; called by muse, mutect2, varscan2
- RANBP6 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV52390534; called by muse, mutect2, varscan2
- RET | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.908); catalogued as COSV60697997; called by muse, mutect2, varscan2
- RNF182 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs768587531, COSV70369651; called by muse, mutect2, varscan2
- SCN4A | c.4433C>T p.S1478L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs201911612; called by muse, mutect2, varscan2
- SEMA3C | c.847T>G p.F283V | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54851714; called by muse, mutect2, varscan2
- SEMA3F | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as rs780169693, COSV50032380; called by muse, mutect2, varscan2
- SEMG1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as rs183367221, COSV54871677; called by muse, mutect2, varscan2
- SETBP1 | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773328311, COSV56329776; called by muse, mutect2, varscan2
- SGSM2 | c.2293G>C p.A765P (on ENST00000426855 / NM_001098509.2; = p.A810P on NM_014853.3) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52159724, COSV52159855; called by muse, mutect2, varscan2
- SHPRH | c.1760G>A p.G587E | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99262008; called by muse, mutect2
- SIRT1 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs1224464761, COSV53019308; called by muse, mutect2, varscan2
- SLC26A4 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55918323; called by muse, mutect2, varscan2
- SLC32A1 | c.596C>G p.P199R | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV54147649; called by muse, mutect2, varscan2
- SLC4A8 | c.2384T>G p.I795S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60655867; called by muse, mutect2, varscan2
- SMTN | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763053737, COSV60780678; called by muse, mutect2, varscan2
- SOX6 | c.500G>C p.R167T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.187); catalogued as COSV57044345; called by muse, mutect2
- SP1 | c.304C>T p.Q102* (on ENST00000327443 / NM_138473.3; = p.Q95* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV59404277; called by muse, mutect2, varscan2
- SPAG5 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.095); catalogued as rs375467524, COSV58803057; called by muse, mutect2, varscan2
- STK36 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199736780; called by muse, mutect2, varscan2
- SYNE1 | c.19768C>T p.Q6590* (on ENST00000367255 / NM_182961.4; = p.Q6519* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as COSV55039539; called by muse, mutect2, varscan2
- TG | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.133); catalogued as rs765016841, COSV55086355; called by muse, mutect2, varscan2
- TNS1 | c.2686C>T p.R896W | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201163809, COSV50729726; called by muse, mutect2, varscan2
- TPX2 | c.1341G>T p.K447N | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as rs1352716423, COSV55921024; called by muse, mutect2, varscan2
- TRO | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 13/20 reads (65%) | catalogued as COSV51503624; called by muse, mutect2, varscan2
- TTN | c.48172C>T p.R16058C (on ENST00000591111; = p.R8634C on NM_003319.4) | Missense Mutation (SNP) | VAF 38/215 reads (18%) | PolyPhen probably damaging (0.973); catalogued as rs760963888, COSV59996285; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- TTN | c.36227C>A p.T12076K (on ENST00000591111; = p.T4652K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | PolyPhen probably damaging (0.997); catalogued as COSV60200180; called by muse, mutect2, varscan2
- UNC13C | c.1727G>T p.S576I | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV52882944; called by muse, mutect2, varscan2
- USP44 | c.1198G>T p.V400F | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs934767732, COSV51565606; called by muse, mutect2, varscan2
- VCAN | c.7365C>A p.S2455R | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV54110992; called by muse, mutect2, varscan2
- VCAN | c.7582G>A p.E2528K | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs772985425, COSV54098569, COSV54110999; called by muse, mutect2, varscan2
- ZBED9 | c.589A>G p.M197V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV71729620; called by muse, mutect2
- ZNF474 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV56946860; called by muse, mutect2, varscan2
- ZNF569 | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV57597295; called by muse, mutect2, varscan2
- ZNF831 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1471088747, COSV100926057, COSV64042904; called by muse, mutect2, varscan2
- CDKN2A | c.130del p.Y44Tfs*9 | Frame Shift Del (DEL) | VAF 44/134 reads (33%) | called by mutect2, pindel, varscan2
- IFNA16 | c.338dup p.Q114Pfs*5 | Frame Shift Ins (INS) | VAF 9/89 reads (10%) | called by mutect2, pindel, varscan2
- NAPB | c.548dup p.I184Dfs*3 | Frame Shift Ins (INS) | VAF 53/156 reads (34%) | called by mutect2, varscan2
- NAPB | c.547delinsAA p.E183Kfs*4 | Frame Shift Ins (INS) | VAF 51/214 reads (24%) | called by mutect2*, pindel, varscan2*
- RFX1 | c.2394C>A p.D798E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.074); called by muse, mutect2
- ZFR2 | c.1490G>T p.R497L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2
- ABHD16B | c.816C>T p.F272= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs766220781, COSV53863477; called by muse, mutect2, varscan2
- ADCY8 | c.3306C>T p.G1102= | Silent (SNP) | VAF 78/354 reads (22%) | catalogued as rs145809062; called by muse, mutect2, varscan2
- ARHGAP12 | c.729T>C p.Y243= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV60964938; called by muse, mutect2, varscan2
- C1orf87 | c.999C>A p.R333= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV64597942; called by muse, mutect2, varscan2
- CALCOCO1 | c.1149C>T p.S383= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV50417844; called by muse, mutect2, varscan2
- CHST13 | c.843G>A p.A281= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV60042754; called by muse, mutect2, varscan2
- COL6A3 | c.6798C>T p.T2266= | Silent (SNP) | VAF 55/144 reads (38%) | catalogued as rs116541926, COSV55086329, COSV55099072; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DMRT1 | c.141C>T p.A47= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV66522948; called by muse, mutect2
- DMXL1 | c.7734C>T p.N2578= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs1221244052, COSV60716985; called by muse, mutect2, varscan2
- DRD5 | c.333G>A p.A111= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV58578285; called by muse, mutect2, varscan2
- DSCAML1 | c.6300G>A p.K2100= (on ENST00000321322; = p.K2040= on NM_020693.4) | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as COSV58397046; called by muse, mutect2, varscan2
- FLNB | c.573G>A p.P191= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs777288549, COSV55874856, COSV55881977; called by muse, mutect2, varscan2
- GPR45 | c.996C>T p.R332= | Silent (SNP) | VAF 111/251 reads (44%) | catalogued as rs1163725148, COSV51525069; called by muse, mutect2, varscan2
- GRHL2 | c.579C>T p.D193= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as rs144668624; called by muse, mutect2, varscan2
- GRM4 | c.1626C>T p.C542= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as rs758454758, COSV65216138, COSV65216815; called by muse, mutect2, varscan2
- IFIT1B | c.837G>A p.E279= | Silent (SNP) | VAF 10/166 reads (6%) | catalogued as COSV65663599; called by muse, mutect2
- IL12RB1 | c.1260C>G p.A420= | Silent (SNP) | VAF 13/172 reads (8%) | catalogued as COSV59098268; called by muse, mutect2
- INF2 | c.1713G>A p.K571= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV53034446; called by muse, mutect2, varscan2
- IRF2BP1 | c.1005C>A p.T335= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV56193532, COSV56194418; called by muse, mutect2, varscan2
- ITGA8 | c.2355G>A p.A785= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs145199076, COSV65225383; called by muse, mutect2, varscan2
- KCNH5 | c.1095C>T p.C365= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV59768535; called by muse, mutect2, varscan2
- KIAA1109 | c.11370C>T p.D3790= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV52683382; called by muse, mutect2, varscan2
- LRRTM1 | c.513C>T p.N171= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs755195234, COSV54444317, COSV99702818; called by muse, mutect2, varscan2
- NEB | c.5418G>A p.K1806= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV50835969, COSV51437587; called by muse, mutect2, varscan2
- NUDCD3 | c.1077G>A p.V359= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV100622023; called by muse, varscan2
- NUMBL | c.352C>T p.L118= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV53286381; called by muse, mutect2, varscan2
- PCDHB3 | c.1845C>T p.F615= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as COSV50597541; called by muse, mutect2
- PLCG2 | c.921C>T p.D307= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs533700490, COSV63872801; called by muse, mutect2, varscan2
- PNLIP | c.1152G>A p.K384= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV65041334; called by muse, mutect2, varscan2
- PSMA7 | c.381T>C p.F127= | Silent (SNP) | VAF 82/196 reads (42%) | catalogued as rs374005966; called by muse, mutect2, varscan2
- PTCHD3 | c.552C>T p.F184= | Silent (SNP) | VAF 174/396 reads (44%) | catalogued as rs764224948, COSV71256611; called by muse, mutect2, varscan2
- SIPA1L2 | c.1998G>A p.T666= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs754022709, COSV53391497; called by muse, mutect2, varscan2
- SLIRP | c.6G>T p.A2= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs374317411; called by muse, mutect2
- SORCS1 | c.339G>A p.A113= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs749403360, COSV53864103; called by muse, mutect2, varscan2
- SPAG17 | c.1848G>A p.G616= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV60458826; called by muse, mutect2, varscan2
- SVEP1 | c.6714C>T p.V2238= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as rs775187334, COSV52835801; called by muse, mutect2, varscan2
- SYBU | c.897C>A p.I299= (on ENST00000276646 / NM_001099754.2; = p.I298= on NM_017786.6) | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs367900187; called by muse, mutect2, varscan2
- TTN | c.41823C>T p.G13941= (on ENST00000591111; = p.G6517= on NM_003319.4) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV60200148; called by muse, mutect2, varscan2
- TTYH2 | c.420C>T p.S140= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as rs776159063, COSV53912008; called by muse, mutect2, varscan2
- XDH | c.1845C>T p.H615= | Silent (SNP) | VAF 46/273 reads (17%) | catalogued as rs756999209, COSV65150122; called by muse, mutect2, varscan2
- XIAP | c.576A>G p.T192= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV100848858; called by muse, mutect2
- ZNF438 | c.153G>A p.L51= | Silent (SNP) | VAF 80/267 reads (30%) | catalogued as COSV59198177; called by muse, mutect2, varscan2
- ZNF492 | c.1467C>T p.S489= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV71762187; called by muse, mutect2, varscan2
- CFAP46 | c.966+225G>A | Intron (SNP) | VAF 11/27 reads (41%) | catalogued as rs908167910, COSV63952006; called by muse, mutect2, varscan2
- GABRG2 | c.-1G>A | 5'UTR (SNP) | VAF 6/47 reads (13%) | catalogued as rs780572044, COSV100729682; called by muse, mutect2, varscan2
- HERC2P3 | n.2280G>T | RNA (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948436 G>A | 3'Flank (SNP) | VAF 25/225 reads (11%) | catalogued as COSV57520070; called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895748 G>A | 5'Flank (SNP) | VAF 104/174 reads (60%) | catalogued as rs1267117323, COSV100019129; called by muse, varscan2
